Somatic mutation profile of tumor specimen C3N-00148-02 (aliquot CPT0081590009) from CPTAC case C3N-00148, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.9 years (19,314 days).
Specimen C3N-00148-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5f297a2-47e8-45f1-b1a3-099fa18aec6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00148-71 (Blood Derived Normal), aliquot CPT0081700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3450aeff-bad3-40ca-9587-ecad6d6dfc76

The open-access MAF lists 89 somatic variants for this specimen: 65 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 14, Frame Shift Del 9, Intron 5, Nonsense Mutation 3, 3'UTR 3, 5'UTR 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.350G>A p.W117* | Nonsense Mutation (SNP) | VAF 39/185 reads (21%) | hotspot (GDC flag); catalogued as rs1559428056, CM141838, CM961425, COSV56542825, COSV56544265, COSV56548887; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGXT2 | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV51491132; called by muse, mutect2, varscan2
- DPY19L1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs762478422, COSV60581164; called by muse, mutect2, varscan2
- FCAR | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV62029575; called by muse, mutect2, varscan2
- KCNJ3 | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99715379; called by muse, mutect2, varscan2
- MGAT1 | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 115/363 reads (32%) | PolyPhen probably damaging (0.992); catalogued as rs1311974324, COSV57135272; called by muse, mutect2, varscan2
- NT5E | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 77/339 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs374757389; called by muse, mutect2, varscan2
- PCNX4 | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1331372813; called by muse, mutect2, varscan2
- PIGV | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.778); catalogued as COSV50290595; called by muse, mutect2, varscan2
- RYR3 | c.10105G>T p.A3369S (on ENST00000389232; = p.A3370S on NM_001036.6) | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.341); catalogued as COSV66791793; called by muse, mutect2, varscan2
- SNRNP200 | c.5940G>T p.E1980D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV55530281; called by muse, mutect2
- TENM4 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as COSV53669886; called by muse, mutect2, varscan2
- ACSF2 | c.852dup p.N285Qfs*11 | Frame Shift Ins (INS) | VAF 25/161 reads (16%) | called by mutect2, pindel, varscan2
- ADD3 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | called by muse, varscan2
- ADGRD2 | c.2904C>G p.D968E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- AMY2B | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ARHGEF19 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ARHGEF2 | c.2008G>T p.V670L (on ENST00000361247 / NM_001162383.2; = p.V642L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BSCL2 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 61/410 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- BTNL9 | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 30/282 reads (11%) | called by muse, mutect2, varscan2
- CCL19 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DAP3 | c.811A>G p.R271G | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DDX20 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- DES | c.1144del p.A382Pfs*13 | Frame Shift Del (DEL) | VAF 49/334 reads (15%) | called by mutect2, pindel, varscan2
- DRAXIN | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DYNLL2 | c.215A>T p.H72L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FCN1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GABRA1 | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GREB1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); called by mutect2, varscan2
- HYAL4 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- IGF2BP1 | c.935del p.I312Tfs*18 | Frame Shift Del (DEL) | VAF 29/134 reads (22%) | called by mutect2, pindel, varscan2
- ITM2B | c.774del p.F258Lfs*6 | Frame Shift Del (DEL) | VAF 35/224 reads (16%) | called by mutect2, pindel, varscan2
- KDM3B | c.2912T>A p.L971Q | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MACF1 | c.2026A>T p.M676L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- MAN2B1 | c.2876A>G p.N959S | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- MAP1A | c.7271G>T p.S2424I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- METAP2 | c.189_190del p.V64Gfs*2 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel, varscan2
- MUTYH | c.1415G>C p.W472S | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NADSYN1 | c.1586A>T p.Y529F | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NAV3 | c.5490G>T p.Q1830H (on ENST00000397909 / NM_001024383.2; = p.Q1808H on NM_014903.6) | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2
- NCAPD3 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NDST1 | c.602del p.N201Tfs*9 | Frame Shift Del (DEL) | VAF 30/175 reads (17%) | called by mutect2, pindel, varscan2
- OTOL1 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PBRM1 | c.2328del p.L776Ffs*2 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- PCDHA5 | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 97/660 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PITPNM2 | c.1515del p.Q506Rfs*26 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- PKP4 | c.2298C>G p.N766K | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRR3 | c.377A>C p.E126A | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PTPRE | c.1299G>C p.L433F | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF138 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RNFT1 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RPRD2 | c.3389A>G p.D1130G | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RSPH6A | c.1286T>C p.F429S | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SKOR2 | c.803C>A p.A268D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.826); called by muse, mutect2
- SPTY2D1 | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK38 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SUGT1 | c.295del p.L99* | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- TLR8 | c.1999A>T p.T667S (on ENST00000218032 / NM_138636.5; = p.T685S on NM_016610.4) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TNN | c.1355A>T p.D452V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- UNC13B | c.936A>T p.E312D | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTP4 | c.1578T>A p.N526K | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WDR33 | c.3522del p.G1175Efs*106 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- ZNF292 | c.6332A>C p.Y2111S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ZNF414 | c.508T>A p.Y170N | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNHIT2 | c.862dup p.H288Pfs*40 | Frame Shift Ins (INS) | VAF 30/137 reads (22%) | called by mutect2, pindel, varscan2
- ABCA13 | c.1038C>G p.V346= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV70045746; called by muse, mutect2, varscan2
- ADGRB2 | c.3474C>T p.C1158= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as rs1274144556, COSV99926696; called by muse, mutect2, varscan2
- CACNA2D2 | c.1869G>T p.R623= | Silent (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- DOCK7 | c.5382T>A p.V1794= (on ENST00000635253 / NM_001367561.1; = p.V1763= on NM_033407.3) | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- FAM161A | c.1392T>C p.H464= | Silent (SNP) | VAF 45/301 reads (15%) | called by muse, mutect2, varscan2
- HEPACAM | c.1065C>T p.I355= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- KLHL11 | c.180C>T p.S60= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs782083223; called by muse, varscan2
- MAPRE2 | c.6T>C p.P2= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- PCDH7 | c.1491C>T p.A497= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV100687715; called by muse, mutect2
- REST | c.799T>C p.L267= | Silent (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- SORBS2 | c.2061G>A p.R687= | Silent (SNP) | VAF 52/339 reads (15%) | catalogued as rs775418076; called by muse, mutect2, varscan2
- TSPAN31 | c.108C>G p.G36= | Silent (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- VIT | c.1284C>A p.T428= (on ENST00000389975 / NM_001177969.1; = p.T443= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- ZNF676 | c.1467C>T p.A489= (on ENST00000650058; = p.A457= on NM_001001411.3) | Silent (SNP) | VAF 78/374 reads (21%) | catalogued as COSV68094387; called by muse, mutect2, varscan2
- AIP | c.-35C>A | 5'UTR (SNP) | VAF 28/164 reads (17%) | called by muse, varscan2
- COLEC11 | c.130+1724G>T | Intron (SNP) | VAF 53/286 reads (19%) | called by muse, mutect2, varscan2
- MDH2 | c.-50C>A | 5'UTR (SNP) | VAF 119/432 reads (28%) | catalogued as rs1554584381; called by muse, mutect2, varscan2
- SEC23B | c.*48del | 3'UTR (DEL) | VAF 32/223 reads (14%) | called by mutect2, pindel, varscan2
- SFT2D1 | c.*44T>C | 3'UTR (SNP) | VAF 16/90 reads (18%) | catalogued as rs758972323; called by muse, mutect2, varscan2
- SYP | c.102+48G>T | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- TPT1 | c.102+234A>G | Intron (SNP) | VAF 31/216 reads (14%) | catalogued as rs1203014676; called by muse, mutect2, varscan2
- TRIM41 | c.909+19C>T | Intron (SNP) | VAF 34/191 reads (18%) | catalogued as rs367715726; called by muse, mutect2, varscan2
- VPS13A | c.100+24C>G | Intron (SNP) | VAF 30/201 reads (15%) | catalogued as COSV62424786; called by muse, mutect2, varscan2
- ZNF467 | c.*113C>T | 3'UTR (SNP) | VAF 16/328 reads (5%) | catalogued as rs1292918625; called by muse, mutect2
